CCDI case PBCGHD — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/098ac96f-1e87-4540-bac7-3b795a73a51d

Demographics
Sex at birth: male.

Diagnoses (1)
1. Pilocytic astrocytoma: ICD-O-3 morphology code: 9421/1; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 5.7 years (2,079 days).

Biospecimens (3 samples)
- Sample 0DS4L5: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DS4MC: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
- Sample 0DS4MI: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
